MMRF case MMRF_1999 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/10e80d8a-797e-4efb-bda0-b3271f7207b4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 53.4 years (19,504 days); ISS stage: II; Days to last known disease status: 1,032 days (2.8 years); Days to last follow up: 1,032 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 4 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 10 days; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 14 days; Days to treatment end: 56 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 121 days; Days to treatment end: 121 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1: M Protein 5.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 43.2 mg/dL; Immunoglobulin G 2.77 g/L; Immunoglobulin A 62.2 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 1.77 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.63 mmol/L; Albumin 38 g/L; Total Protein 11.1 g/dL; Glucose 5.17 mmol/L.
- Day 56 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 6.41 g/L; Immunoglobulin A 0.932 g/L; Immunoglobulin M 1.19 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.
- Day 148 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 5.25 g/L; Immunoglobulin A 0.345 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.62 mmol/L.
- Day 220 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 0.426 g/L; Immunoglobulin M 0.241 g/L; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.34 mmol/L.
- Day 339 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 6.69 g/L; Immunoglobulin A 0.494 g/L; Immunoglobulin M 0.478 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 451 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 6.75 g/L; Immunoglobulin A 0.406 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 234 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 542 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8.5 g/L; Immunoglobulin A 0.424 g/L; Immunoglobulin M 0.48 g/L; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.28 mmol/L.
- Day 633 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8.13 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.
- Day 724 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 4.95 mmol/L.
- Day 815 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 0.66 g/L; Immunoglobulin M 0.67 g/L; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.45 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.17 mmol/L.
- Day 906 (ECOG 0): Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 5.12 mmol/L.
- Day 1,032: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 7.93 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 45 g/L; Total Protein 7.2 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -1: Weight: 50 kg; Height: 159 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Lymphoma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Leukemia; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1999_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1999_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
